Somatic mutation profile of tumor specimen TCGA-AP-A0L8-01A (aliquot TCGA-AP-A0L8-01A-11W-A062-09) from TCGA case TCGA-AP-A0L8, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC2; Tumor grade: G3; Age at diagnosis: 70.5 years (25,733 days).
Specimen TCGA-AP-A0L8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f156a493-f9aa-4b23-b9be-384507aa8295.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AP-A0L8-10A (Blood Derived Normal), aliquot TCGA-AP-A0L8-10A-01W-A062-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d3959ed3-a2a1-4d60-ae7a-7f3eecaee547

The open-access MAF lists 67 somatic variants for this specimen: 52 protein-altering or splice-affecting, 15 silent.
By variant classification: Missense Mutation 44, Silent 15, Nonsense Mutation 3, Splice Site 2, Frame Shift Del 1, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 49/53 reads (92%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AASS | c.152C>G p.T51S | Missense Mutation (SNP) | VAF 76/166 reads (46%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.915); catalogued as COSV62791193; called by muse, mutect2, varscan2
- ACTR1A | c.136C>T p.R46C | Missense Mutation (SNP) | VAF 53/110 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs758983075, COSV64023890; called by muse, mutect2, varscan2
- ADGRF1 | c.1727T>G p.F576C | Missense Mutation (SNP) | VAF 62/158 reads (39%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.527); catalogued as COSV51947120; called by muse, mutect2
- APOBR | c.2468G>A p.R823K (on ENST00000431282; = p.R832K on NM_018690.4) | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.49); PolyPhen benign (0.035); catalogued as COSV60493025; called by muse, mutect2, varscan2
- ARHGAP17 | c.1954G>A p.G652R (on ENST00000289968 / NM_001006634.3; = p.G574R on NM_018054.6) | Missense Mutation (SNP) | VAF 26/29 reads (90%) | SIFT deleterious (0); PolyPhen possibly damaging (0.482); catalogued as rs1413364245, COSV51510676; called by muse, mutect2, varscan2
- CCDC18 | c.3691C>T p.H1231Y (on ENST00000343253 / NM_001306076.1; = p.H1232Y on NM_206886.4) | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as COSV58146452; called by muse, mutect2, varscan2
- CELF3 | c.748G>A p.A250T | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.521); catalogued as rs201319891, COSV51885176; called by muse, mutect2, varscan2
- CFAP221 | c.1289G>A p.R430Q | Missense Mutation (SNP) | VAF 63/149 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774688531, COSV54653535; called by muse, mutect2, varscan2
- CFHR2 | c.356G>A p.R119K | Missense Mutation (SNP) | VAF 116/262 reads (44%) | SIFT tolerated (0.46); PolyPhen benign (0.01); catalogued as COSV66380601; called by muse, mutect2, varscan2
- CHD4 | c.3350G>A p.G1117D (on ENST00000357008 / NM_001363606.2; = p.G1130D on NM_001273.5) | Missense Mutation (SNP) | VAF 92/158 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58907912; called by muse, mutect2, varscan2
- CMBL | c.650G>T p.R217L | Missense Mutation (SNP) | VAF 75/165 reads (45%) | SIFT tolerated (0.14); PolyPhen benign (0.224); catalogued as rs147855838, COSV56984891; called by muse, mutect2, varscan2
- COX15 | c.169A>G p.T57A | Missense Mutation (SNP) | VAF 70/79 reads (89%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV50012926; called by muse, mutect2, varscan2
- CR1L | c.1508C>T p.T503I | Missense Mutation (SNP) | VAF 222/454 reads (49%) | SIFT tolerated (0.15); PolyPhen benign (0.178); catalogued as rs746929002, COSV54329781; called by muse, mutect2
- DCBLD2 | c.1309C>G p.Q437E | Missense Mutation (SNP) | VAF 112/275 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.055); catalogued as COSV58789723, COSV58792094; called by muse, mutect2, varscan2
- DSCAM | c.4089C>A p.N1363K | Missense Mutation (SNP) | VAF 52/206 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV68032945; called by muse, mutect2, varscan2
- DST | c.18434C>T p.A6145V (on ENST00000361203 / NM_001374722.1; = p.A3842V on NM_015548.5) | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.712); catalogued as COSV55032439; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.2254C>T p.R752W | Missense Mutation (SNP) | VAF 42/107 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); catalogued as rs377161686; called by muse, mutect2, varscan2
- FMN2 | c.1305G>C p.Q435H | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.459); catalogued as COSV60445424; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.731T>A p.V244D | Missense Mutation (SNP) | VAF 16/155 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.908); catalogued as COSV58558444, COSV58562185; called by muse, mutect2, varscan2
- GABPA | c.160C>G p.L54V | Missense Mutation (SNP) | VAF 60/103 reads (58%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.628); catalogued as COSV61397227; called by muse, mutect2, varscan2
- GAREM1 | c.517C>T p.R173* | Nonsense Mutation (SNP) | VAF 77/174 reads (44%) | catalogued as rs925385479, COSV52514231; called by muse, mutect2, varscan2
- GBF1 | c.4402C>A p.Q1468K (on ENST00000369983 / NM_001377137.1; = p.Q1467K on NM_004193.3) | Missense Mutation (SNP) | VAF 43/179 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.378); catalogued as COSV64147808; called by muse, mutect2, varscan2
- H2AZ2 | c.229C>A p.L77I | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV56062148, COSV56062905; called by muse, mutect2
- IGHV5-51 | c.127G>T p.G43C | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.393); catalogued as rs549160451; called by muse, mutect2, varscan2
- IL17RE | c.1073-2A>C p.X358_splice | Splice Site (SNP) | VAF 74/141 reads (52%) | catalogued as COSV55970157, COSV55970554; called by muse, mutect2, varscan2
- KCNB1 | c.2116G>T p.A706S | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated, low confidence (0.93); PolyPhen benign (0.02); catalogued as rs779750227, COSV65566501, COSV65570216; called by muse, mutect2, varscan2
- MAG | c.1801G>T p.D601Y | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as COSV104423184, COSV62702230; called by muse, mutect2, varscan2
- METTL15 | c.361G>A p.D121N | Missense Mutation (SNP) | VAF 36/175 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57722566; called by muse, mutect2, varscan2
- NTRK2 | c.2414C>G p.T805S (on ENST00000323115 / NM_001369534.1; = p.T821S on NM_006180.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/82 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV52859040, COSV52875616; called by muse, mutect2, varscan2
- OLAH | c.508A>G p.K170E (on ENST00000378228 / NM_001039702.3; = p.K223E on NM_018324.3) | Missense Mutation (SNP) | VAF 24/99 reads (24%) | SIFT tolerated (0.51); PolyPhen benign (0.043); catalogued as COSV65493765; called by muse, mutect2, varscan2
- OR52I2 | c.641T>A p.L214* | Nonsense Mutation (SNP) | VAF 74/346 reads (21%) | catalogued as COSV57045895; called by muse, mutect2, varscan2
- OR8B2 | c.17A>G p.N6S | Missense Mutation (SNP) | VAF 121/469 reads (26%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.015); catalogued as COSV66665219; called by muse, mutect2, varscan2
- PSD2 | c.1000C>T p.R334W | Missense Mutation (SNP) | VAF 22/28 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs771869390, COSV51206758, COSV99217466; called by muse, mutect2, varscan2
- RAB30 | c.524G>C p.R175T | Missense Mutation (SNP) | VAF 69/156 reads (44%) | SIFT tolerated (0.26); PolyPhen benign (0.094); catalogued as COSV52627895; called by muse, mutect2, varscan2
- RAD21 | c.1850A>G p.Y617C | Missense Mutation (SNP) | VAF 200/380 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV52062296; called by muse, mutect2, varscan2
- RNASEH1 | c.774+1G>T p.X258_splice | Splice Site (SNP) | VAF 194/442 reads (44%) | catalogued as COSV59439434; called by muse, mutect2, varscan2
- SPOP | c.419A>G p.D140G | Missense Mutation (SNP) | VAF 170/336 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.849); catalogued as COSV100753413, COSV61653958, COSV61655208; called by muse, mutect2, varscan2
- SYT12 | c.1106G>A p.R369H | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs373132081; called by muse, mutect2, varscan2
- TLR10 | c.2242C>G p.L748V | Missense Mutation (SNP) | VAF 34/141 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.912); catalogued as COSV58301719; called by muse, mutect2, varscan2
- TOR3A | c.1000C>T p.P334S | Missense Mutation (SNP) | VAF 16/303 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); catalogued as rs1309009762, COSV61680635; called by muse, mutect2
- UACA | c.2452T>C p.S818P | Missense Mutation (SNP) | VAF 121/194 reads (62%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as COSV59858370; called by muse, mutect2, varscan2
- UGT1A6 | c.299C>A p.A100D | Missense Mutation (SNP) | VAF 58/166 reads (35%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as COSV59395286; called by muse, mutect2
- UPF3B | c.494A>T p.E165V | Missense Mutation (SNP) | VAF 45/127 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV52231098; called by muse, mutect2, varscan2
- UPF3B | c.493G>T p.E165* | Nonsense Mutation (SNP) | VAF 46/128 reads (36%) | catalogued as COSV52231109; called by muse, mutect2, varscan2
- USP26 | c.1676T>C p.L559P | Missense Mutation (SNP) | VAF 32/252 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.445); catalogued as COSV63709434; called by muse, mutect2, varscan2
- VIT | c.949G>T p.A317S (on ENST00000389975 / NM_001177969.1; = p.A332S on NM_053276.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 51/97 reads (53%) | SIFT tolerated (0.38); PolyPhen benign (0.031); catalogued as COSV64898503; called by muse, mutect2, varscan2
- VPS45 | c.1015T>C p.S339P | Missense Mutation (SNP) | VAF 33/132 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV64888677; called by muse, mutect2, varscan2
- ZDHHC6 | c.681G>A p.Q227= | Splice Region (SNP) | VAF 90/200 reads (45%) | catalogued as COSV65564981; called by muse, mutect2
- ZFAND5 | c.401_415del p.P134_S139delinsR | In Frame Del (DEL) | VAF 26/35 reads (74%) | catalogued as COSV52989267; called by mutect2, pindel, varscan2
- ZNF408 | c.337T>G p.S113A | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV61238978; called by muse, mutect2, varscan2
- MAP3K4 | c.872del p.I291Tfs*32 | Frame Shift Del (DEL) | VAF 31/336 reads (9%) | called by mutect2, pindel
- ABCA6 | c.3402C>T p.F1134= | Silent (SNP) | VAF 14/84 reads (17%) | catalogued as COSV52642710; called by muse, mutect2, varscan2
- COL13A1 | c.1506C>T p.R502= (on ENST00000398978 / NM_001130103.2; = p.R445= on NM_080798.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/21 reads (43%) | catalogued as rs754892079, COSV62568712; ClinVar: likely benign; called by muse, mutect2, varscan2
- FAM169A | c.1896T>C p.A632= | Silent (SNP) | VAF 86/97 reads (89%) | catalogued as COSV57188724; called by muse, mutect2, varscan2
- MPP3 | c.549C>G p.L183= | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as COSV68198974; called by muse, mutect2, varscan2
- MYO16 | c.687G>A p.A229= | Silent (SNP) | VAF 31/355 reads (9%) | catalogued as rs537076680, COSV51800858; called by muse, mutect2
- MYO5A | c.5019G>A p.S1673= | Silent (SNP) | VAF 48/79 reads (61%) | catalogued as rs768731860, COSV62563155; called by muse, mutect2, varscan2
- NETO1 | c.537C>T p.S179= | Silent (SNP) | VAF 86/302 reads (28%) | catalogued as rs375973052; called by muse, mutect2, varscan2
- NLRP1 | c.1212G>A p.R404= | Silent (SNP) | VAF 51/57 reads (89%) | catalogued as COSV52567256; called by muse, mutect2, varscan2
- PRKCG | c.1368T>C p.H456= | Silent (SNP) | VAF 38/69 reads (55%) | catalogued as rs1391065993, COSV54731227; called by muse, mutect2, varscan2
- TEX13A | c.558T>G p.G186= | Silent (SNP) | VAF 15/47 reads (32%) | catalogued as COSV61172597; called by muse, mutect2, varscan2
- TTC4 | c.315C>G p.G105= | Silent (SNP) | VAF 20/84 reads (24%) | catalogued as COSV64885069; called by muse, mutect2, varscan2
- UPRT | c.165C>T p.Y55= | Silent (SNP) | VAF 13/29 reads (45%) | catalogued as COSV64912604; called by muse, mutect2, varscan2
- VPS33A | c.594C>T p.C198= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as rs370198408; called by muse, mutect2, varscan2
- ZNF224 | c.639C>T p.F213= | Silent (SNP) | VAF 147/320 reads (46%) | catalogued as COSV61243096; called by muse, mutect2, varscan2
- ZNF501 | c.234T>C p.Y78= | Silent (SNP) | VAF 61/181 reads (34%) | catalogued as rs1363799172, COSV68516546; called by muse, mutect2, varscan2
